Surgical pathology report (de-identified scan), TCGA case TCGA-Y8-A8RZ, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site Spectrum Health, specimen TCGA-Y8-A8RZ-01A (Primary Tumor).

[page 1 of 3]
Research Gross Description

male with renal mass

Research Dx

Right renal mass, partial nephrectomy:

Papillary renal cell carcinoma type 2 (see case summary).

CCF
7AD 0-3
Carcinoma, papillary renal cell
8260/3
path
Adenocarcinoma, mucinous
8480/3
Site @ Kidney NOS
C64.9
JP 11/17/14

CASE SUMMARY FOR NEPHRECTOMY FOR RENAL CELL CARCINOMA:

Procedure: Partial nephrectomy

Specimen laterality: Right

Tumor site: Anterior upper pole, per operative report

Tumor size: 1.3 cm

Extent of disease: Tumor limited to kidney.

Histologic type: Papillary type 2

Sarcomatoid features: Not identified

Histologic grade (Fuhrman Nuclear Grade): Not applicable to papillary subtype

Margins: Uninvolved by invasive carcinoma

Lymphovascular invasion: Not identified

Pathologic staging (pTNM): as follows:

Primary tumor: pT1 (tumor 7 cm or less, limited to the kidney)

Regional lymph nodes: pNx, lymph nodes not sampled

Distant metastasis: Not applicable

Pathologic findings in nonneoplastic kidney: Focal chronic inflammation

Other tumors and/or tumor-like lesions: Not identified

AJCC Staging (7th edition) pT1 pNX pM- not applicable

Right colon, partial colectomy:

Mucinous Adenocarcinoma (see case summary). See comment 1.

CASE SUMMARY FOR COLON AND RECTUM: Resection, Including Transanal Disk Excision of Rectal Neoplasms

Tumor site: Transverse colon, per operative report

Tumor size: Unknown size of the primary tumor (previously partially resected)

Macroscopic tumor perforation: None detected

Macroscopic intactness of mesorectum: Not applicable

Histologic type: Mucinous adenocarcinoma

Histologic grade: High grade

Microscopic tumor extension: Tumor invades muscularis propria

Margins: Negative

Proximal margin: Negative

Distal margin: Negative

Circumferential (radial) or mesenteric margin: Negative

Distance of invasive carcinoma from closest margin: 3.5 cm from the distal margin

Treatment effect: Not applicable

Lymphovascular invasion: Not identified

Perineural invasion: Not identified

Tumor deposits (discontinuous extramural extension): Not applicable

Type of polyp in which invasive carcinoma arose: Tubulovillous adenoma with at high grade dysplasia (per previous report at outside institution)

Pathologic Staging (pTNM):

[page 2 of 3]
Primary tumor (pT): pT2, tumor invades muscularis propria
Regional lymph nodes (pN): pN0, no regional lymph node involvement

Number examined: 22

Number involved: 0

Distant metastasis (pM): pM-not applicable

Additional pathologic findings: Previous biopsy site with tattoo, appendix with no pathologic abnormality

AJCC Staging (7th edition): pT2 pN0 pM- not applicable

Research QC

Tumor:

100% tumor nuclei (all Type 1); I reviewed the diagnostic slides and this tumor is a mixture of Type 1 and 2

0% necrosis

0% normal

Normal:

100% benign kidney

Research Specimen

—

Specimen Process Time

Blood draw time:

Plasma frozen time:

Serum frozen time

Buffy coat frozen time:

Cold ischemia start time:

Formalin fixation start time:

Total cold ischemia time

Formalin fixation stopped time

Total formalin fixation time:

Specimen Weight

Normal

1-76 mg

Tumor

1-103 mg

Specimen Size

Plasma x 2

Serum x 2

Buffy coat x 1

Cryovials x 2

Normal x 1

Tumor x 1

FFPE x 2

Normal x 1

Tumor x 1

Study

[page 3 of 3]
Patient Consent
Yes

Criteria	hw 11/26/13	Yes	No
Dual/Synchronous Primary	Colorectal	✓	✓

Source: NCI Genomic Data Commons file e008b428-0730-4d76-a8c5-ae492eba36ee (TCGA-Y8-A8RZ.F70E4C81-2FD6-4AA2-9AB3-3896914CF4D4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).